Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8MM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8MM-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name
Med. Rec. #:
DOB:
Soc. Sec. #:
Physician(s):

Visit #:
Sex: Male
Location:

Accession #:
Service Date:
Received:
Client:

FINAL PATHOLOGIC DIAGNOSIS

- A. Right pelvic lymph nodes, regional dissection: No tumor in four lymph nodes (0/4).
- B. Left pelvic lymph nodes, regional dissection: No tumor in six lymph nodes (0/6).
- C. Prostate and bilateral seminal vesicles, radical prostatectomy: Prostatic adenocarcinoma, Gleason score $4+3=7$ with a minor component of 5, with focal extraprostatic extension; see comment.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Right anterior apex (slides C3, C4, and C5), right posterior base (slide C8), left posterior apex, mid, and base (slides C9, C10, C11, and C12), and left anterior mid (slide C14).
- **Estimated volume of tumor:** 3.2 cubic centimeters.
- **Gleason score:** 7; primary pattern 4, secondary pattern 3 and tertiary 5.
- **Estimated volume > Gleason pattern 3:** 2.9 cubic centimeters.
- **Involvement of capsule:** Present (slide C12).
- **Extraprostatic extension:** Present, focal (slide C12).
- **Margin status for tumor:**
- Negative.
- **Margin status for benign prostate glands:**
- Benign glands present at inked excision margins; right and left apex, slides C1/C2.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; extensive.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present.
- **Lymphovascular invasion:** Present, best seen on slide C11.
- **Lymph node status:**
- Negative; total number of nodes examined: 10.
- **AJCC/UICC stage:** pT3aN0.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1123/14

[page 2 of 3]
Specimen(s) Received

A: Right pelvic lymph nodes
B: Left pelvic lymph nodes
C: Prostate & BSV (fresh)

Clinical History

The patient is _____ man. Review of the electronic medical record _____ reveals a positive family history _____ of prostate cancer. The patient has been followed for many years with serial PSA testing, which was steadily rising _____ and subsequently lead to ultrasound needle core biopsies of the prostate performed at _____ and reviewed at _____ in consultation _____, confirming the diagnosis of prostatic adenocarcinoma, Gleason grade 4+4, of the left lateral base. A subsequent bone scan was negative, and the patient undergoes a radical prostatectomy with bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "right pelvic lymph nodes," consists of a single irregular, unoriented segment of soft, yellow-tan, fibrofatty tissue (5 x 2.5 x 1.5 cm). Three firm, ovoid, pink-tan lymph node candidates (1.5-2.0 cm) are identified. The entire specimen is submitted as follows:

- A1: One lymph node candidate, bisected.
- A2: One lymph node candidate, bisected.
- A3: One lymph node candidate, bisected.
- A4: Remaining fibrofatty remnant. _____

Part B, additionally labeled "left pelvic lymph nodes," consists of two segments of soft, irregular, unoriented, yellow-tan fibrofatty tissue (4 x 3.5 x 1 cm in aggregate). Six ovoid to irregular, pink-tan, soft lymph node candidates (0.4-2.3 cm) are identified. The entire specimen is submitted as follows:

- B1-B2: One lymph node candidate, bisected.
- B3: Two lymph node candidates, bisected.
- B4: Three lymph node candidates, intact.
- B5: Remaining fibrofatty remnant. _____

Part C, additionally labeled "prostate and BSV," consists of a radical prostatectomy specimen (35 gm; 4 cm from apex to base x 4.5 cm in width x 3 cm from anterior to posterior) with attached seminal vesicle/vas deferens bundles (right 4 x 2 x 0.5 cm, left 5 x 2 x 0.5 cm).

GROSS PATHOLOGIC FINDINGS: There is a single solid, white, roughly lobular tumor (1.8 x 0.6 x 1.5 cm) noted in the left lateral mid gland through base (slices 4-8) which abuts the lateral capsule in all involved slices. No other masses or lesions are identified. The remaining peripheral tissue is pink-tan and semi-porous. The central-transitional zone is slightly lobular and makes up approximately 20% of total gland volume. The anterior fibrous stroma is open. The remaining capsule has been surgically incised and sutured closed prior to receipt in Pathology.

ORIENTED BY: Anatomic landmarks.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

POTENTIAL STUDIES: Tissue is snap frozen for research purposes.

GROSS PHOTOGRAPHS: Yes, cut section (serial slice 5).

TOTAL NUMBER OF SLICES: 10 (inclusive of apical margin).

[page 3 of 3]
AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

C1: Right apex.

C2: Left apex.

Right anterior quadrant

C3: Slice 3.

C4: Slice 5.

C5: Slice 7.

Right posterior quadrant

C6: Slice 3.

C7: Slice 5.

C8: Slice 7.

Left posterior quadrant

C9: Slice 3.

C10: Slice 5.

C11: Slice 7.

C12: Slice 8, perpendicular section, to evaluate margin.

Left anterior quadrant

C13: Slice 3.

C14: Slice 5.

C15: Slice 7.

Bladder margins, entirely submitted in perpendicular sections

C16: Right.

C17: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

C18: Right.

C19: Left. [REDACTED]

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Source: NCI Genomic Data Commons file 7d1df446-5a91-4b5a-a3a2-aca572bbfbbb (TCGA-V1-A8MM.2FBA596B-858D-4043-BDCF-CCE582A74D67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).